Somatic mutation profile of tumor specimen MBCProject_3946_T2_WES (aliquot MBCProject_3946_T2_WES_1) from CMI case MBCProject_3946, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 49.7 years (18,137 days).
Specimen MBCProject_3946_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Bone; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8538e36-9c05-4d4e-be35-f9817d8a976f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3946_SALIVA (Saliva), aliquot MBCProject_3946_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/973637f8-e6b3-45b2-9a74-d4a3e88506fb

The open-access MAF lists 61 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 26, Missense Mutation 8, In Frame Del 5, Silent 5, Frame Shift Del 4, RNA 4, Splice Site 4, 5'Flank 2, 3'UTR 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD5 | c.548del p.G183Vfs*28 | Frame Shift Del (DEL) | VAF 3/22 reads (14%) | catalogued as rs1266056996; called by pindel, varscan2
- CPN2 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs141360992; called by mutect2, varscan2
- KIAA0895 | c.958G>A p.A320T (on ENST00000297063 / NM_001100425.2; = p.A269T on NM_015314.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs762985580; called by mutect2, varscan2
- NLE1 | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs554861899; called by mutect2, varscan2
- NPIPB15 | c.132C>G p.H44Q | Missense Mutation (SNP) | VAF 46/332 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs763190214, COSV70437206; called by muse, varscan2
- PRRC2C | c.1687C>A p.Q563K (on ENST00000367742; = p.Q561K on NM_015172.4) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs868576903; called by mutect2, varscan2
- ZNF107 | c.2146T>G p.S716A | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs879023898; called by mutect2, varscan2
- ZNF107 | c.2147C>G p.S716* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as rs879203277; called by mutect2, varscan2
- AP1G2 | c.1678_1698del p.L560_E566del | In Frame Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel
- ARHGAP1 | c.1102_1131+3del p.X368_splice | Splice Site (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- CASP7 | c.185_226del p.M62_N75del | In Frame Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- CFAP43 | c.254_300del p.R85Qfs*27 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- DHX29 | c.41C>G p.A14G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- EGFR | c.3163C>T p.L1055= | Splice Region (SNP) | VAF 5/36 reads (14%) | called by mutect2, varscan2
- EGR1 | c.944_987del p.L315Qfs*17 | Frame Shift Del (DEL) | VAF 5/74 reads (7%) | called by mutect2, pindel
- GOLGA8M | c.385A>T p.R129W | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.227); called by muse, varscan2
- PILRB | c.456_486del p.X152_splice | Splice Site (DEL) | VAF 7/52 reads (13%) | called by mutect2, varscan2*
- PTPRZ1 | c.2196_2237del p.R733_S746del | In Frame Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, varscan2*
- RBL2 | c.2948_2986del p.A983_S995del | In Frame Del (DEL) | VAF 5/62 reads (8%) | called by mutect2, pindel
- SCARA3 | c.227-7_231del p.X76_splice | Splice Site (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- SEPTIN4 | c.439del p.A147Lfs*13 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, varscan2
- SRSF10 | c.702_737del p.Q238_S249del | In Frame Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- TRIOBP | c.6477_6485del p.X2159_splice (on ENST00000644935 / NM_001039141.3; = p.X446_splice on NM_007032.5) | Splice Site (DEL) | VAF 6/63 reads (10%) | called by mutect2, pindel
- DBX1 | c.549G>A p.L183= | Silent (SNP) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- FAM47C | c.1041C>T p.P347= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs781838965, COSV63726283; called by muse, varscan2
- GPR21 | c.660G>A p.Q220= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV65378982, COSV65379295; called by mutect2, varscan2
- GRIN2A | c.3861C>T p.S1287= | Silent (SNP) | VAF 12/143 reads (8%) | catalogued as rs1447951387; called by muse, mutect2
- ZNF836 | c.2400T>C p.H800= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, varscan2
- ACAD9 | c.633+757A>G | Intron (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- ADCK1 | c.219+5397A>G | Intron (SNP) | VAF 8/39 reads (21%) | catalogued as rs1399190570; called by muse, varscan2
- AL591926.7 | n.312T>A | RNA (SNP) | VAF 24/146 reads (16%) | catalogued as rs62556841; called by muse, varscan2
- ARHGAP8 | c.299+278T>C | Intron (SNP) | VAF 10/64 reads (16%) | catalogued as rs1199925933, COSV104396514; called by muse, varscan2
- BRD1 | c.2360-226_2360-216del | Intron (DEL) | VAF 3/39 reads (8%) | called by mutect2, pindel
- CDK10 | c.87+901A>G | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as rs1334746439; called by muse, varscan2
- CFDP1 | c.65-4340C>A | Intron (SNP) | VAF 5/26 reads (19%) | called by mutect2, varscan2
- EDRF1 | c.2371+161A>G | Intron (SNP) | VAF 12/64 reads (19%) | catalogued as rs1299179669; called by muse, varscan2
- EI24 | c.189-357T>C | Intron (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- ETFA | c.664+732T>C | Intron (SNP) | VAF 14/131 reads (11%) | called by muse, varscan2
- FAM53C | c.136+19T>G | Intron (SNP) | VAF 6/40 reads (15%) | catalogued as rs1390623498; called by muse, varscan2
- GTF2H4 | c.375-69A>G | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, varscan2
- KATNBL1 | c.883-623_883-584del | Intron (DEL) | VAF 5/88 reads (6%) | called by mutect2, varscan2*
- MATR3 | c.*1448A>G | 3'UTR (SNP) | VAF 10/56 reads (18%) | catalogued as rs1298787056; called by muse, varscan2
- MGAT3 | c.-1-1143A>G | Intron (SNP) | VAF 7/72 reads (10%) | called by muse, varscan2
- MTHFD2L | c.805+16239T>C | Intron (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2
- NASP | c.60-2535dup | Intron (INS) | VAF 6/33 reads (18%) | catalogued as rs1415971471; called by pindel, varscan2
- NDUFAF1 | c.759+581A>G | Intron (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2
- RNF4 | c.125-1317G>A | Intron (SNP) | VAF 15/123 reads (12%) | catalogued as rs1319401008; called by muse, varscan2
- SDSL | c.-143-1380C>T | Intron (SNP) | VAF 10/60 reads (17%) | catalogued as rs1327470680; called by muse, varscan2
- SLC4A8 | c.2172+4996A>G | Intron (SNP) | VAF 8/54 reads (15%) | called by muse, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23763A>G | Intron (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- SNORD116-5 | chr15:25062310 del GTCCCACCTCTTCAAATGTGCTTGGATCGATGATGA | RNA (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- SNX29 | c.247+2193T>G | Intron (SNP) | VAF 17/128 reads (13%) | called by muse, varscan2
- STAG3L2 | n.1023G>T | RNA (SNP) | VAF 20/126 reads (16%) | catalogued as rs1554426472; called by muse, varscan2
- SUMO1 | c.12+6842T>G | Intron (SNP) | VAF 6/42 reads (14%) | catalogued as rs758916105, COSV104432441; called by mutect2, varscan2
- THEM4 | c.287-807A>G | Intron (SNP) | VAF 10/82 reads (12%) | catalogued as rs1483716190, COSV64296099; called by muse, varscan2
- TMEM255B | c.190-145T>A | Intron (SNP) | VAF 6/59 reads (10%) | catalogued as rs1317749925; called by mutect2, varscan2
- TUBGCP2 | c.616+586A>G | Intron (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2
- VPS37A | c.125+967T>C | Intron (SNP) | VAF 17/134 reads (13%) | catalogued as rs1161501599; called by muse, mutect2, varscan2
- ZDHHC19 | chr3:196214237 T>C | 5'Flank (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- ZNF559 | chr19:9324200 T>C | 5'Flank (SNP) | VAF 9/64 reads (14%) | catalogued as rs1165892942; called by muse, mutect2, varscan2
- ZNF833P | n.1200G>A | RNA (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2
